Somatic mutation profile of tumor specimen MP2PRT-PARUIM-TMP1-A (aliquot MP2PRT-PARUIM-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PARUIM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.1 years (2,947 days).
Specimen MP2PRT-PARUIM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b94073c5-8922-4667-97e7-7763a857a379.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARUIM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARUIM-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53267cda-494c-462c-9b9b-eac4b6bd8813

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, 3'Flank 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF2 | c.1451G>A p.R484H (on ENST00000296862 / NM_001368115.2; = p.R416H on NM_153839.7) | Missense Mutation (SNP) | VAF 120/372 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370408589, COSV57291596; called by muse, mutect2, varscan2
- ANKRD30A | c.2716G>T p.D906Y (on ENST00000611781; = p.D850Y on NM_052997.2) | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs757312417; called by muse, mutect2, varscan2
- CTU2 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 122/382 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs371031341; called by muse, mutect2
- CYP2B6 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148520554; called by muse, mutect2, varscan2
- DQX1 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 127/384 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs749983331, COSV66353228; called by muse, mutect2, varscan2
- LRCH2 | c.1962C>T p.N654= | Splice Region (SNP) | VAF 71/164 reads (43%) | catalogued as rs782377324, COSV57762435; called by muse, mutect2, varscan2
- MAGI2 | c.1738G>A p.G580S | Missense Mutation (SNP) | VAF 24/458 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs373777210; called by muse, mutect2
- POPDC2 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 149/464 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.14); catalogued as rs762501897, COSV51740998; called by muse, mutect2, varscan2
- PTPN11 | c.1504T>C p.S502P | Missense Mutation (SNP) | VAF 82/361 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as CM022450, CM055504, COSV61005465, COSV61007751, COSV61015981; called by muse, mutect2, varscan2
- TBX21 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 174/470 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs756244998; called by muse, mutect2, varscan2
- CSGALNACT1 | c.892G>T p.V298F | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DUSP21 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 129/309 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- FAM171B | c.308T>C p.V103A | Missense Mutation (SNP) | VAF 12/414 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HS6ST3 | c.59T>C p.V20A | Missense Mutation (SNP) | VAF 99/383 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC19 | c.275G>A p.G92D | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2
- PHF20 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 65/224 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLC18A2 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 119/393 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ADRA1A | c.1386C>T p.N462= | Silent (SNP) | VAF 126/300 reads (42%) | catalogued as rs201746874; called by muse, mutect2, varscan2
- C4orf54 | c.153G>A p.S51= | Silent (SNP) | VAF 152/719 reads (21%) | catalogued as rs887728793; called by muse, mutect2, varscan2
- OR5AP2 | c.633T>C p.F211= | Silent (SNP) | VAF 105/374 reads (28%) | catalogued as COSV57258048; called by muse, mutect2, varscan2
- PSG9 | c.1239C>A p.V413= | Silent (SNP) | VAF 82/283 reads (29%) | catalogued as COSV99392032; called by muse, mutect2, varscan2
- ZNF729 | c.3582C>A p.G1194= | Silent (SNP) | VAF 36/155 reads (23%) | called by muse, mutect2, varscan2
- BTBD7 | chr14:93333371 C>A | 5'Flank (SNP) | VAF 58/457 reads (13%) | catalogued as rs571711987; called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406873 del C | 3'Flank (DEL) | VAF 77/194 reads (40%) | called by mutect2, pindel*, varscan2*
